Surgical pathology report (de-identified scan), TCGA case TCGA-J8-A4HY, project TCGA-THCA (Thyroid Carcinoma), tissue source site Mayo Clinic, specimen TCGA-J8-A4HY-01A (Primary Tumor).

[page 1 of 4]
**SurgPath Final
Temporary Copy**

Page 1 of 4

FINAL DIAGNOSIS

A) Thyroid, left lobe, lobectomy: Papillary carcinoma (6.5 cm).

B) Trachea, superior margin, biopsy: Negative for tumor.

C) Lymph nodes, right anterior neck, dissection: Four of seven lymph nodes involved by metastatic papillary carcinoma (see Comment).

Comment: The largest metastasis measures 1.5 cm in greatest dimension.

D) Lymph nodes, right posterior neck, dissection: Six of thirty lymph nodes involved by metastatic papillary carcinoma (see Comment).

Comment: The largest metastasis measure 3.6 cm in greatest dimension.

E) "Residual thyroid tumor", resection: Papillary carcinoma (4.5 cm), extending beyond the thyroid capsule to invade the trachea. Three of three lymph nodes involved by metastatic papillary carcinoma.

**E: Thyroid Gland
HISTOLOGIC TYPE:
Papillary carcinoma
TUMOR FOCALITY:
Unifocal**

*1CD-0-3
carcinoma - papillary, April 8260/3
Site: thyroid, NOS C73.9*

**TUMOR SIZE:
Greatest Dimension: 6.5 cm
HISTOLOGIC GRADE:
Not applicable**

*hw
10/3/12*

PRIMARY TUMOR (pT):

pT4a: Moderately advanced disease. Tumor of any size extending beyond the thyroid capsule to invade subcutaneous soft tissues, larynx, trachea, esophagus or recurrent laryngeal nerve

REGIONAL LYMPH NODES (pN):

pN1b: Metastases to unilateral, bilateral or contralateral cervical (Levels I, II, III, IV, V) or retropharyngeal or superior mediastinal lymph nodes (Level VII).

[page 2 of 4]
NUMBER OF LYMPH NODE(S) INVOLVED::

13

NUMBER OF LYMPH NODE(S) EXAMINED::

40

LYMPH NODE, EXTRANODAL EXTENSION:

Not identified

DISTANT METASTASIS (pM):

Not applicable

MARGINS:

Margins uninvolved by carcinoma

TUMOR CAPSULE:

Partially encapsulated

TUMOR CAPSULAR INVASION:

Present:

LYMPH-VASCULAR INVASION:

Not identified

EXTRATHYROIDAL EXTENSION:

Present

~electronic signature~

SPECIMEN RECEIVED

- A) LEFT THYROID LOBE, F/S
- B) TRACHEA, SUPERIOR MARGIN, F/S
- C) RIGHT ANTERIOR NECK CONTENTS
- D) RIGHT POSTERIOR NECK CONTENTS
- E) RESIDUAL THYROID TUMOR

FROZEN SECTION

- A) Left thyroid lobe: Papillary carcinoma.

Seen with [REDACTED].

- B) Tracheal superior margin: Negative for tumor.

[page 3 of 4]
GROSS DESCRIPTION

A) Received fresh for frozen section labeled "left thyroid lobe" is a 79.3-g unoriented left thyroid lobe measuring 7.5 x 7.0 x 4.0 cm. The capsule is purple/red with multiple fibrous adhesions. The capsule is entirely inked black. Serial sectioning reveals a 6.5 x 5.5 x 4.0 cm cystic lesion filled with tan/pink solid papillary excrescences. Portions of the mass wall are white/gray, thickened and fibrotic. Touch preps of the mass are made and a representative section submitted for frozen section diagnosis and is subsequently submitted as A1. The remainder of the thyroid parenchyma is purple/red, dense and unremarkable. Representative sections are submitted as follows: A2 representative mass to normal thyroid, A3 through A7 representative mass and cyst wall, A8 representative thyroid. A portion of the tissue is submitted for research study [REDACTED]

B) Received fresh for frozen section diagnosis labeled "trachea, superior margin" is an unoriented, irregular fragment of red/tan soft tissue measuring 0.3 cm in greatest dimension. The specimen is entirely submitted for frozen section diagnosis and subsequently submitted in B1.
[REDACTED]

C) Received in formalin labeled "right anterior neck contents" is an unoriented irregular fragment of yellow/pink/gray fibrofatty soft tissue measuring 7.5 x 4.7 x 1.2 cm in aggregate. There is a small amount of red/brown skeletal muscle adhered to the specimen. Eight possible lymph nodes are identified ranging from 0.2 to 1.5 cm in greatest dimension. The nodes are entirely submitted as follows: C1 largest lymph node bisected, C2 four possible intact lymph nodes, C3 three possible intact lymph nodes.

D) Received in formalin labeled "right posterior neck contents" is a 6.5 x 5.0 x 2.3 cm aggregate of yellow/brown lobulated adipose tissue. Multiple possible lymph nodes are identified ranging from 0.2 to 3.6 cm in greatest dimension. Serial sectioning of the two largest lymph nodes reveals tan/white/pink papillary, solid and cystic foci. The lymph nodes are entirely submitted as follows: D1 through D4 paired sections quadrisectioned largest lymph node, D5 through D9 second largest lymph node serially sectioned (paired sections), D10 two bisected nodes (one is dotted orange), D11 five possible intact lymph nodes, D12 six possible intact lymph nodes, D13 six possible intact lymph nodes, D14 five possible intact lymph nodes, D15 five possible intact lymph nodes.

E) Received in formalin labeled "residual thyroid tumor" is a 28-g (formalin fixed)

[page 4 of 4]
unoriented portion of thyroid (6.0 x 3.5 x 2.0 cm) attached to a C-shaped portion of trachea measuring 3.9 cm in length by 2.4 cm in diameter. There is a small amount of adherent red/brown skeletal muscle on the anterior surface of the thyroid. The thyroid capsule is purple/red with fine fibrous adhesions. The mucosa lining the trachea is tan/pink, nodular and appears to be involved by mass. The thyroid and anterior trachea are inked black. The superior tracheal margin is inked orange and the inferior tracheal margin is inked blue. Serial sectioning of the thyroid lobe reveals 4.5 x 2.9 x 2.7 cm gray/white/pink firm nodule that is extending into the tracheal cartilage. The mass abuts the thyroid capsule. There is only a scant amount of red/brown, dense normal-appearing thyroid present. Representative sections are submitted as follows: E1 perpendicular sections of mass invading trachea to include superior tracheal margin, E2 representative sections of mass invading trachea to include inferior tracheal margins, E3 and E4 paired sections bisected full-thickness section showing mass to trachea, E5 through E7 representative mass, E8 representative mass to adjacent normal thyroid tissue, E9 two intact and one bisected possible lymph nodes (the bisected lymph node is dotted orange).

CLINICAL INFORMATION
THYROID MASS

HPA Discrepancy		

Source: NCI Genomic Data Commons file 9e49d791-9e97-4175-8b71-85e58caa3026 (TCGA-J8-A4HY.44A2984E-9B5D-4A22-957D-359C2647589F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).